Surgical pathology report (de-identified scan), TCGA case TCGA-27-1833, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-1833-01A (Primary Tumor).

1
2

TCGA-27-1833

Ref. Number

Gender

Birth date

Tumor site

Right frontal

Histological diagnosis

Glioblastoma multiforme

Source: NCI Genomic Data Commons file f801a725-17f0-4d62-a3f3-3ac3cd5d44c0 (TCGA-27-1833.3D379071-9A4C-4E4D-95B9-3FBE3CDB12C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).